Surgical pathology report (de-identified scan), TCGA case TCGA-66-2734, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2734-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung and other specimens

Clinical diagnosis and question

Right hilum, left lower lobe

REPORT ON FINDINGS**Macroscopy**

1.) Left lung: In filled, fixed condition, left lung of 16 x 11 cm in size at base and up to 28 cm high, central bronchial resection line 3 cm proximal to the branch of the upper lobular bronchus. On the hilum, six blackish and partially damaged nodes of between 0.4 and 2.2 cm in size. The dorsal portion of the gap between the lobes has been largely obliterated. In this region, covering an area of approx. 9 cm, pleura unclearly delimited and discolored whitish, thickened, with flat retraction. Below this, with its main mass located in the border regions of segments 6 and 8 – 10, a moderately solid, pale brownish tumor with unclear demarcation and max. 7.8 cm in size. Eccentrically, a malacic area of approx. 3.5 cm in size. No demonstrable connection to bronchial branches that can be dissected out. Tumor extends as far as the pleura in the region of the retraction and approx. 1.5 cm deep into the upper lobe in the region of S4. Parenchyma indurated peripheral to the tumor and yellow-brownish in color. Color of the rest of the lung tissue normal.

2.) Left hilar LN (station 10): Gray-blackish node of 2 cm in size.

3.) Left pulmonary ligament LN (station 9): Damaged, gray-blackish node of 1.5 cm in size.

4.) Left paraesophageal LN (station 8): Gray-blackish node of 5 cm in size with some surrounding tissue.

5.) Subcarinal LN (station 7): Gray-blackish node of 9 mm in size.

6.) Paraaortic LN (station 6): Damaged, gray-blackish node of 8 mm in size.

7.) Subaortic LN (aortopulmonary window) (station 5): Gray-blackish node of 8 mm in size with some surrounding tissue.

8.) Left prevascular and retrotracheal LN (station 3): Clear portion of the lung of 9 mm in size.

9.) Right hilar LN (station 10): Two damaged gray-blackish nodes of 1 and 1.1 cm in size with some surrounding tissue.

Investigated:

1.) Tumor with lung parenchyma in margin, tumor with pleura, tumor with gap between lobes (upper lobe stained), central bronchial resection line, vascular resection margins (1 larger one split in half + separate in lungs),

2.) – 9.) in each case, entire material (split in half for 8.),

14 blocks, in some cases [REDACTED], PAS, diastase-PAS.

[page 2 of 2]
Microscopy

on 1.) Tumor structure composed of variably sized, partially branched, solid, focal atypical epidermoid epithelia, also focally arranged in trabecular groups. Moderately eosinophilic cytoplasm of intermediate width to wide, partially extended lengthways to spindly. Focal intercellular bridges. Nuclei round to oval, up to strongly anisomorphic, with coarse chromatin, mainly small to moderately large nucleoli and relatively numerous mitoses. Extensive necroses. Desmoplastic tumor stroma and groups of the atypical epithelia infiltrated with mixed inflammatory cells or predominantly with granulocytes. Expansion of the atypical epithelia across the fibrosed obliterated interlobular gap into the neighboring segments of the upper lobe. Dissected visceral pleura also focally infiltrated and notably strongly fibrously expanded here, as well as with superficial fibrin precipitates that are both external and incorporated. Sections of the tumor margins with up to high densities of intraalveolar granulocytes and macrophages, alveolar septa sometimes with strong edematous-fibrous expansion and infiltrated with mixed inflammatory cells, as well as surrounded by proliferated pneumocytes. Resection margin of bronchus and vessels as well as hilar lymph nodes free of tumors. The latter with normal lymphate. Cells with development of numerous activated follicles, minor to moderate deposits of fine-grained blackish pigments and fewer anisotropic particles within macrophages, as well as partially with nodular, fibrous zones with few spindle cells and, in sections, old necrotic zones, sometimes with the inclusion of planar calcium salt precipitates and focally minimal bony tissue.

on 2.) – 5.), 7.), + 9.) Lymph nodes as described under 1.).

on 6.) Incompletely filled peripheral lung tissue with, at the level of the visceral pleura, small, sometimes squashed lymph nodes with normal lymphatic cells and more extended aggregates of macrophages with minor deposits of blackish, grainy pigment.

on 8.) Peripheral lung tissue with subpleurally expanded alveolar spaces and rarefied and enlarged alveolar septa. Mainly pleural, up to moderate deposits of blackish, grainy pigment within macrophages.

EVALUATION

Primary diagnosis/diagnoses: Large, peripheral, bronchopulmonary, partially necrotically altered, with poor differentiation histologically, nonkeratinizing squamous epithelial carcinoma (G3) of the left lower lobe of the lung, located in the border region of segments 6 and 8 to 10.

TNM classification pT2 pN0 R0, Stage IB.

C 34.3 M 8070/3

Secondary diagnosis/diagnoses: Active chronic pneumonia in the areas around the tumor and fibrinous inflammation of the visceral pleura with markedly fibrous expansion over the tumor. Lymph nodes in this region (samples 1.) – 7.) and 9.)) with abnormal reactive changes, anthracotic pigment deposits and sometimes partially calcified, old necrotic or ossified nodular sclerosed zones. Mild focal emphysema of the lung (sample 8.)).

Remark/addendum: The carcinoma has expanded across the lobular gap into the neighboring sections of segment 4 of the upper lobe. The resection margin of the bronchus and vessels as well as all lymph nodes that were removed or those that were identified are tumor-free.

Source: NCI Genomic Data Commons file 30195cac-f640-4c59-8b6d-a5a96c4e08b0 (TCGA-66-2734.5CDA5B60-06F5-411C-805F-0EC3EE89DE67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).